FM case AD16831 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/be1fca1f-ba9c-4583-8f83-0afd582f64b3

Male, 71.8 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the cervix uteri. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
